Somatic mutation profile of tumor specimen MBCProject_0943_T1_WES (aliquot MBCProject_0943_T1_WES_1) from CMI case MBCProject_0943, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 44.4 years (16,234 days).
Specimen MBCProject_0943_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e4c2084-272d-4aa6-9009-7bd2ab4f0386.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0943_SALIVA (Saliva), aliquot MBCProject_0943_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7bcb649-620a-43a8-b16e-46288960f969

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 3, Intron 2, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 16/168 reads (10%) | catalogued as COSV55861718, COSV55871792; called by muse, mutect2
- GSN | c.2258C>G p.P753R | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99049969; called by muse, mutect2, varscan2
- HNF4A | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs147342965, COSV57388658; called by muse, mutect2, varscan2
- LRP2 | c.8879C>T p.P2960L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.876); catalogued as rs1461997028; called by muse, mutect2
- POU4F3 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV57944571; called by muse, mutect2, varscan2
- RAD51AP2 | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs771570880; called by mutect2, varscan2
- BTN3A3 | c.1179del p.R394Dfs*32 | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | called by mutect2, pindel, varscan2
- ENPP5 | c.730T>C p.C244R | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- GATA3 | c.78dup p.H27Afs*26 | Frame Shift Ins (INS) | VAF 98/303 reads (32%) | called by mutect2, pindel, varscan2
- RC3H1 | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 90/161 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLCO1B3 | c.1788_1790del p.D596_K597delinsE | In Frame Del (DEL) | VAF 12/94 reads (13%) | called by mutect2, pindel, varscan2
- SLCO4A1 | c.1616A>C p.E539A | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STAM2 | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.102833C>T p.A34278V (on ENST00000591111; = p.A26854V on NM_003319.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ZKSCAN4 | c.510C>A p.C170* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- GLOD5 | c.411G>A p.G137= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- PNCK | c.342C>T p.S114= (on ENST00000340888 / NM_001366975.1; = p.S197= on NM_001039582.3) | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs782175890; called by muse, mutect2, varscan2
- ZFYVE9 | c.1968C>A p.I656= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV99820711; called by muse, mutect2, varscan2
- CPAMD8 | c.5567+205G>A | Intron (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- MARF1 | c.4814-116T>A | Intron (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2
- SLC7A5P1 | n.533G>C | RNA (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
